Somatic mutation profile of tumor specimen 0DBU0Y from CCDI case PBBLSB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 0.5 years (183 days).
Specimen 0DBU0Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84a2e84a-a495-4ece-8483-7f1ae1274013.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBU0W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/263846a9-9b64-457a-8533-82bb9c098685

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PITPNM1 | c.3008+6C>T | Splice Region (SNP) | VAF 154/351 reads (44%) | called by muse, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 5/43 reads (12%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, varscan2
